Gene-level copy-number profile of tumor specimen C3L-06935-01 from CPTAC case C3L-06935, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G4; Age at diagnosis: 56.5 years (20,623 days).
Specimen C3L-06935-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1e9ceb07-5611-497d-88b0-b3d68bfd7f46.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06935-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/f45ca421-52c7-43ff-bd2a-57f66bcf9317

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 1,524; copy number 2: 53,722; copy number 3: 2,656; copy number 4: 451; copy number 10: 13.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,857,086–12,861,909, 1 gene (within-gene range 0–2): PRAMEF2.
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr19:6,413,348–6,940,459, 29 genes: KHSRP, MIR3940, SLC25A41, SLC25A23, CRB3, DENND1C, AC010503.4, TUBB4A, AC010503.2, AC010503.1, TNFSF9, AC010503.3, CLIC4P2, Y_RNA, CD70, RPL7P50, TNFSF14, C3, AC008760.2, GPR108, MIR6791, TRIP10, AC008760.1, SH2D3A, VAV1, ADGRE1, AC020895.2, AC020895.1, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:90,781,766–91,354,579, 13 genes, copy number 10: RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1.

Autosomal genes at a single copy (total copy number 1): 1,175. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
